Surgical pathology report (de-identified scan), TCGA case TCGA-CF-A9FH, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ILSBio, specimen TCGA-CF-A9FH-01A (Primary Tumor).

[page 1 of 5]
Clinical Case Report **(For Collection of Cancerous Tissue)**

ICD-O 3

Cell Carcinoma, papillary urothelial NOS 8130/3

path Carcinoma, papillary transitional NOS 8130/3

Informed Consent

Site Bladder NOS C67.9

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

4/2/14

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
		☐ Single ☒ Married	Vietnamese	
Gender	Weight	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
☒ Male ☐ Female				

HISTORY OF PRESENT ILLNESS
Chief Complaints: Hematuria
Symptoms: The patient was discovered a hematuria, fatigue, weight loss
Clinical Findings: Weight loss, Hematuria, PTSD discovered a Tumor of bladder with 3cm in greatest dimension
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status
N/A			

OB/GYN HISTORY			
Menopausal Status	Date of First Menses	# of Pregnancies	
☐ Pre-menopausal			
☐ Peri-Menopausal	Date of Last Menses	# of Live Births	
☐ Post-menopausal			
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____	

SOCIAL HISTORY				
Occupation: _____		Environmental Hazards: _____		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO	Oporede	2	(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis
N/A		

LAB DATA							
Test	Result		Date	Test	Result		Date
HIV	☐ Negative ☐ Positive:			CEA	☐ Negative ☐ Positive:		
Hep B	☐ Negative ☐ Positive:			CA 15-3	☐ Negative ☐ Positive:		
Hep C	☐ Negative ☐ Positive:			CA 19-9	☐ Negative ☐ Positive:		
AFP	☐ Negative ☐ Positive:			PSA	☐ Negative ☐ Positive:		
Other:	☐ Negative ☐ Positive:			Other:	☐ Negative ☐ Positive:		
B/T Cell Markers:							

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	Tumor of bladder	
X-Ray	chest is normal	
CT	observation Cancer of bladder	
Endoscopy		
MRI	/ not	
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Tumor of Bladder		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
not	not	
Clinical Staging		Date of Diagnosis
T ₁ N ₀ M ₀	Stage: I	

Treatment Information

SURGICAL TREATMENT		
Procedure		Date of Procedure
Tumor Resection		
Primary Tumor		
Organ	Detailed Location	Size
Bladder	Bladder	3 x 2 x 1 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes	not	
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
not		
Surgical Staging		
T ₁	N ₀	M ₀ Stage: I

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Microscopic Description

Histological Pattern											
Cell Distribution					Structural Pattern						
	+	-							+	-	
Diffuse	✓				Streaming						✓
Mosaic		✓			Storiform						✓
Necrosis		✓			Fibrosis						✓
Lymphocytic Infiltration		✓			Palisading						✓
Vascular Invasion		✓			Cystic Degeneration						✓
Clusterized		✓			Bleeding						✓
Alveolar Formation		✓			Myxoid Change						✓
Indian File		✓			Psammoma/Calcification						✓

Cellular Differentiation											
Squamous			Adenomatous			Sarcomatous			Lymphomatous		
	+	-		+	-		+	-		+	-
Squamoid Cell		✓	Glandular cell	✓		Round Cell		✓	Large Cell		✓
Spindle Cell		✓	Cell Stratification	✓		Fibroblast		✓	Small Cell		✓
Keratin		✓	Secretion		✓	Osteoblast		✓	RS Cell/RS Like		✓
Desmosome		✓	Intracyt. Vacuole		✓	Lipoblast		✓	Inflam. Cell		✓
Pearl		✓	Gland formation		✓	Myoblast		✓	Plasma Cell		✓

Cellular Differentiation: Well ✓ Moderate Poor

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		✓		
Hyperchromatism		✓		
Nucleolar Prominent		✓		
Multinucleated Giant Cell	✓			
Mitotic Activity		✓		
Nuclear Grade:		✓		

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Urothelial Carcinoma, Low grade
Grade: 1

Comments:

Principal Investigator

Pathologist

Date

[page 5 of 5]
Consolidated Pathology Diagnosis

Histological Pattern											
Cell Distribution			Structural Pattern			Cellular Differentiation			Nuclear Appearance		
	+	-		+	-		+	-		+	-
Diffuse		☒	Streaming			Squamous	☒		Adenomatous		
Mosaic	☒		Storiform			Spindle Cell	☒		Glandular cell		
Necrosis		☒	Fibrosis			Keratin			Cell Stratification		
Lymphocytic Infiltration	☒		Palisading			Desmosome			Secretion		
Vascular Invasion		☒	Cystic Degeneration			Pearl			Intracyt. Vacuole		
Clusterized	☒		Bleeding						Gland formation		
Alveolar Formation		☒	Myxoid Change								
Indian File		☒	Psammoma/Calcification								
Cellular Differentiation											
Nuclear Appearance											
Cellular Differentiation: ☒ Well ☐ Moderate ☐ Poor											
Nuclear Atypia:											
Nuclear Grade:											

Final Pathology Report

Histological Diagnosis: poorly differentiated transitional cell carcinoma **Grade:** II

Comments:

Director, Research Pathology

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

PATHOLOGISTS

Date

Reviewed In (Date):	Date Reviewed: 12/20/13	

Source: NCI Genomic Data Commons file 7353f4ec-4f89-4586-a570-7163132305bc (TCGA-CF-A9FH.3F6B75DD-B8BE-42A1-AF6A-73B030EDD6FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).